Somatic mutation profile of tumor specimen TCGA-P4-A5ED-01A (aliquot TCGA-P4-A5ED-01A-11D-A28G-10) from TCGA case TCGA-P4-A5ED, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 51.2 years (18,698 days).
Specimen TCGA-P4-A5ED-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a3f42fc-b1fa-4e9a-9a6c-c7605c6e494a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-P4-A5ED-11A (Solid Tissue Normal), aliquot TCGA-P4-A5ED-11A-11D-A28G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40fdc33c-dec9-4070-a240-386cbd473f20

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV61370996; called by muse, mutect2, varscan2
- DCLRE1B | c.1300C>T p.H434Y | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV65813414; called by muse, mutect2, varscan2
- GRAMD1B | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); catalogued as COSV59211587; called by muse, mutect2, varscan2
- MTA3 | c.618C>A p.F206L | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); catalogued as COSV68137006; called by muse, mutect2
- NBN | c.1165A>G p.M389V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV55377662; called by muse, mutect2, varscan2
- RNF128 | c.1153+1G>A p.X385_splice (on ENST00000255499 / NM_194463.2; = p.X359_splice on NM_024539.3) | Splice Site (SNP) | VAF 31/129 reads (24%) | catalogued as rs1156474179, COSV55255254; called by muse, mutect2, varscan2
- SEL1L | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV60923078; called by muse, mutect2, varscan2
- WDSUB1 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 26/257 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63068357; called by muse, mutect2
- HS3ST4 | c.824_827del p.H275Pfs*8 | Frame Shift Del (DEL) | VAF 11/103 reads (11%) | called by pindel, varscan2
- KIF19 | c.610C>A p.R204= | Silent (SNP) | VAF 50/182 reads (27%) | catalogued as COSV63430791; called by muse, varscan2
- SERPINB6 | c.366C>G p.L122= (on ENST00000612421 / NM_001271823.2; = p.L103= on NM_004568.6) | Silent (SNP) | VAF 9/85 reads (11%) | catalogued as COSV59567833; called by muse, mutect2, varscan2
- SNX2 | c.1101T>G p.L367= | Silent (SNP) | VAF 7/123 reads (6%) | catalogued as COSV65349382; called by muse, mutect2
- TAF1L | c.2268C>T p.G756= | Silent (SNP) | VAF 20/256 reads (8%) | catalogued as COSV54271405; called by muse, mutect2
- WDFY3 | c.5568A>G p.Q1856= | Silent (SNP) | VAF 35/137 reads (26%) | catalogued as COSV55716052; called by muse, mutect2, varscan2
